Gene-level copy-number profile of tumor specimen C3N-01200-02 from CPTAC case C3N-01200, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 56.3 years (20,550 days).
Specimen C3N-01200-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 78266926-2895-4650-8e41-92430954bb6e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01200-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,219 have no estimate.
https://portal.gdc.cancer.gov/files/b7aa5c6a-7a00-4e58-bed1-fae03487601b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3,502; copy number 1: 3,512; copy number 2: 47,965; copy number 3: 2,915; copy number 4: 506; copy number 10: 4.

Caution: 3,502 autosomal genes are at 0 copies in this file, far more than a typical tumor; the lists below are given as recorded.

Homozygous deletions (total copy number 0; autosomes only): 3,502 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:132,401,253–132,722,459, 7 genes (within-gene range 0–2): NIP7P2, DNAJC13, ACAD11, NPHP3-ACAD11, ACKR4, HSPA8P19, UBA5.
- chr8:98,633,547–98,633,865, 1 gene (within-gene range 0–2): AP003467.2.
- chr10:14,061–133,761,125, 2,259 genes (broad region; genes not listed).
- chr14:60,398,934–106,879,812, 1,235 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:94,759,259–94,761,116, 2 genes, copy number 10: CYP4F32P, AC073464.1.
- chr10:133,778,246–133,778,699, 2 genes, copy number 10: RPL23AP60, BX322534.1.

Autosomal genes at a single copy (total copy number 1): 3,512. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
